CCDI case PBBZFA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/9ea408e5-45c5-4bdd-8e1f-2afb30521fa0

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Desmoplastic small round cell tumor: ICD-O-3 morphology code: 8806/3; Tissue or organ of origin: Liver; Age at diagnosis: 12.2 years (4,474 days).

Biospecimens (3 samples)
- Sample 0DLBM0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLBMI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLBMS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
